Somatic mutation profile of tumor specimen 0DXV6I from CCDI case PBBNLI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell carcinoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 12.4 years (4,540 days).
Specimen 0DXV6I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 204319b1-553a-4ca8-b404-8c4d35644b51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXV66 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeefdc48-09f6-44aa-aa70-1ef721d574c1

The open-access MAF lists 63 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Intron 6, 3'UTR 3, Nonsense Mutation 2, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH7 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100543117; called by muse, mutect2, varscan2
- HCCS | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 8/264 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.801); catalogued as rs1369775030; called by muse, mutect2
- ITGA10 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV65196406; called by muse, mutect2
- JPH3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227305136, COSV52467570; called by muse, mutect2
- LRRIQ1 | c.3143C>T p.S1048L | Missense Mutation (SNP) | VAF 115/343 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV101279399; called by muse, mutect2, varscan2
- PITX2 | c.469G>T p.G157W (on ENST00000354925 / NM_001204397.1; = p.G164W on NM_000325.6) | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100146183, COSV100146270; called by muse, mutect2
- PKD2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 18/623 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV99417063; called by muse, mutect2
- PRRC2A | c.2126G>C p.G709A | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.833); catalogued as rs903683259; called by muse, mutect2, varscan2
- RFX4 | c.596C>T p.S199F (on ENST00000392842 / NM_213594.3; = p.S105F on NM_032491.6) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1451031749, COSV57578907; called by muse, varscan2
- SLC9A6 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 35/382 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.264); catalogued as rs782624170; called by muse, mutect2
- SPDL1 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 224/615 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99517554; called by muse, mutect2, varscan2
- TDRD5 | c.2793G>T p.Q931H | Missense Mutation (SNP) | VAF 52/707 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54251079; called by muse, mutect2
- ZADH2 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100463369; called by muse, mutect2
- ZAR1L | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 143/293 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100564019; called by muse, mutect2, varscan2
- AGPAT4 | c.522C>G p.H174Q | Missense Mutation (SNP) | VAF 28/754 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2
- AHNAK2 | c.2818G>C p.G940R | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AJM1 | c.2455G>T p.A819S | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKRD50 | c.2866G>T p.E956* | Nonsense Mutation (SNP) | VAF 249/937 reads (27%) | called by muse, mutect2, varscan2
- APOB | c.10477G>T p.E3493* | Nonsense Mutation (SNP) | VAF 34/506 reads (7%) | called by muse, mutect2
- DIRAS1 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, mutect2
- DPP10 | c.1052C>G p.T351S | Missense Mutation (SNP) | VAF 21/399 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- EDNRB | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 128/222 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO30 | c.282G>C p.W94C | Missense Mutation (SNP) | VAF 23/794 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCGR2B | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 212/657 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.21508A>G p.T7170A | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- MYO16 | c.5395C>A p.Q1799K | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- NT5C2 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- OR8A1 | c.593T>A p.V198D | Missense Mutation (SNP) | VAF 48/539 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PACS2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PCDHGA12 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SLC34A1 | c.531C>T p.G177= | Splice Region (SNP) | VAF 48/662 reads (7%) | called by muse, mutect2
- TMEM61 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 21/622 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2
- TTBK1 | c.2953C>A p.L985M | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.088); called by muse, mutect2
- TUBGCP6 | c.3119C>A p.A1040D | Missense Mutation (SNP) | VAF 148/471 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- VGF | c.730A>C p.T244P | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); called by muse, mutect2
- ADCY10 | c.519C>T p.D173= | Silent (SNP) | VAF 48/704 reads (7%) | catalogued as rs758174086; called by muse, mutect2
- ANKRD62 | c.27G>A p.A9= | Silent (SNP) | VAF 204/358 reads (57%) | catalogued as COSV58410769; called by muse, mutect2, varscan2
- AVPR2 | c.747G>A p.R249= | Silent (SNP) | VAF 82/314 reads (26%) | called by muse, mutect2, varscan2
- CDH4 | c.648C>A p.P216= | Silent (SNP) | VAF 53/288 reads (18%) | catalogued as rs145846676, COSV100848895; called by muse, mutect2, varscan2
- CHRNA3 | c.879C>T p.T293= | Silent (SNP) | VAF 56/664 reads (8%) | called by muse, mutect2
- EMILIN1 | c.2889C>A p.P963= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- HSPA2 | c.1372C>T p.L458= | Silent (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- LGI3 | c.507C>A p.G169= | Silent (SNP) | VAF 44/250 reads (18%) | called by muse, mutect2, varscan2
- POGK | c.1596G>A p.A532= | Silent (SNP) | VAF 210/614 reads (34%) | catalogued as rs770826223, COSV63311745; called by muse, mutect2, varscan2
- PPP3CB | c.42C>A p.P14= | Silent (SNP) | VAF 114/283 reads (40%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2634C>T p.P878= | Silent (SNP) | VAF 107/428 reads (25%) | catalogued as rs782510943; called by muse, mutect2, varscan2
- RSPH9 | c.282G>A p.A94= | Silent (SNP) | VAF 50/662 reads (8%) | catalogued as rs151197990; called by muse, mutect2
- SLC4A9 | c.144G>T p.L48= | Silent (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- STOML3 | c.642G>A p.A214= | Silent (SNP) | VAF 104/179 reads (58%) | called by muse, mutect2, varscan2
- SUZ12 | c.2037C>G p.T679= | Silent (SNP) | VAF 154/531 reads (29%) | called by muse, mutect2, varscan2
- ZFYVE27 | c.771G>T p.L257= | Silent (SNP) | VAF 54/590 reads (9%) | called by muse, mutect2
- AP3B2 | c.*30C>A | 3'UTR (SNP) | VAF 38/384 reads (10%) | called by muse, mutect2
- CDH4 | c.*29G>T | 3'UTR (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- DGKB | c.-78T>A | 5'UTR (SNP) | VAF 63/155 reads (41%) | called by muse, mutect2, varscan2
- GDAP1 | c.579+68A>T | Intron (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- GRK4 | c.-88A>G | 5'UTR (SNP) | VAF 8/62 reads (13%) | catalogued as rs1245734236; called by muse, mutect2, varscan2
- MCF2L | c.3166-89G>T | Intron (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- MUC19 | n.5791T>C | RNA (SNP) | VAF 31/652 reads (5%) | called by muse, mutect2
- PDE4B | c.281+74191T>C | Intron (SNP) | VAF 31/738 reads (4%) | called by muse, mutect2
- PDHA1 | c.*1246C>A | 3'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as rs923800219; called by muse, mutect2, varscan2
- PPFIA2 | c.645+13A>G | Intron (SNP) | VAF 92/296 reads (31%) | called by muse, mutect2, varscan2
- RND2 | c.190+91G>A | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- TMEM231 | c.310-78G>A | Intron (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
